Surgical pathology report (de-identified scan), TCGA case TCGA-CG-5716, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-5716-01A (Primary Tumor).

*** Diagnosis: ***

1. to 3.: Gastrectomy specimen and secondary esophageal resection specimen with tumor-free oral and aboral resection margins and including a moderately differentiated adenocarcinoma or gastric carcinoma located in the prepyloric antrum with infiltration of all wall layers and penetration of the peritoneum, with five regional lymph node metastases and peritoneal carcinosis (pT4a L1 V0 R0 pN2 5/52 pM1), and a poorly differentiated, partially mucinous Barrett's adenocarcinoma located in the area of the esophagogastric junction (pT3 L0 V0 R0 pN0 0/52).

CGA-CG-5716

Source: NCI Genomic Data Commons file bc92cf18-0643-41f5-8497-7ba7ddc2b576 (TCGA-CG-5716.E9500B56-0443-4ABE-8080-08FAD2CCB096.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).